Somatic mutation profile of tumor specimen TCGA-QQ-A8VD-01A (aliquot TCGA-QQ-A8VD-01A-42D-A38Z-09) from TCGA case TCGA-QQ-A8VD, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Abdominal fibromatosis; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 56.8 years (20,729 days).
Specimen TCGA-QQ-A8VD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a08f38d9-4293-4483-b421-28bd8039fab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A8VD-10A (Blood Derived Normal), aliquot TCGA-QQ-A8VD-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebee4232-c56b-4f34-ac0d-ca4b6e9f422f

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FREM1 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs375644504, COSV101085755; called by muse, mutect2
- LRFN4 | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540930; called by muse, mutect2
- PHF23 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99139007; called by muse, mutect2
- ABCA5 | c.1770T>C p.N590= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV101201322; called by muse, mutect2
- SLC13A4 | c.1194C>G p.V398= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV100819002; called by muse, mutect2, varscan2
